CCDI case PBCWJE — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/97393f3f-7352-49db-90e1-dd3e9a0bf204

Demographics
Sex at birth: female.

Biospecimens (2 samples)
- Sample 0E1NYP: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0E1NZX: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
